Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IJ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IJ-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT EXTERNAL/ INTERNAL ILIAC, HYPOGASTRIC AND OBTURATOR LYMPH NODES:
METASTATIC ADENOCARCINOMA IN ONE OF THIRTEEN LYMPH NODES ,
LESS THAN 1.0 MM FOCUS. NO EXTRANODAL EXTENSION PRESENT. (1/13)
- (B) RIGHT EXTERNAL/ INTERNAL ILIAC, HYPOGASTRIC AND OBTURATOR LYMPH NODES:
Twenty one lymph nodes, no tumor present (0/21).
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

COE *ICD 8.3*
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 061.9
9/21/24/13

GROSS DESCRIPTION

- (A) LEFT EXTERNAL/ INTERNAL ILIAC HYPOGASTRIC AND OBTURATOR LYMPH NODES - Multiple fragments of fatty tissue measuring in aggregate 9.0 x 7.0 x 1.5 cm. Dissection reveals multiple possible lymph nodes ranging from 0.6 up to 2.0 cm in their greatest dimension. Possible lymph nodes are entirely submitted.
- SECTION CODE: A1, three possible lymph nodes; A2, three possible lymph nodes; A3, one sectioned possible lymph node; A4, one sectioned possible lymph node; A5, one sectioned possible lymph node; A6, one sectioned possible lymph node; A7, one sectioned possible lymph node; A8, one sectioned possible lymph node; A9, one sectioned possible lymph node; A10, A11, one sectioned possible lymph node; A12, A13, one sectioned possible lymph node.
- (B) RIGHT EXTERNAL/ INTERNAL ILIAC, HYPOGASTRIC AND OBTURATOR LYMPH NODES - Multiple fragments of fatty tissue measuring in aggregate, 9.0 x 8.0 x 2.0 cm. Dissection reveals multiple possible lymph nodes ranging from 0.5 up to 2.5 cm in their greatest dimension. Possible lymph nodes are entirely submitted in cassettes B1, five possible lymph nodes; B2, five possible lymph nodes; B3, five possible lymph nodes; B4, four possible lymph nodes; B5, three possible lymph nodes; B6, one sectioned possible lymph node; B7, one sectioned possible lymph node; B8, one sectioned possible lymph node; B9, one sectioned possible lymph node; B10, one sectioned possible lymph node; B11, B12, one sectioned possible lymph node; B13, B14, one sectioned possible lymph node.
- (C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 4]
Page: 2

Accession: [REDACTED]

Specimen Date/Time: [REDACTED]

[page 3 of 4]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3) WITH TERTIARY GLEASON GRADE 5 COMPONENT. (SEE COMMENT)
TUMOR INVADING INTRAPROSTATIC PORTION OF RIGHT SEMINAL VESICLE.
TUMOR INVADING FOCALLY RIGHT BLADDER NECK.
MARGINS OF RESECTION FREE OF TUMOR.
VASCULAR/LYMPHATIC INVASION PRESENT.
Left seminal vesicle and segments of vasa deferentia, no tumor present.
SEE PREVIOUS REPORT FOR DIAGNOSIS OF PELVIC LYMPH NODES.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor is located in the right anterolateral, right lateral, right posterolateral, right posterior, mid posterior, left posterior, left posterolateral and left lateral peripheral zone. The tumor focus measures 3.0 x 2. cm in the largest cross-sectional dimension and it is present in three cross sections and extensively in the apex and base regions. The tumor invades focally the right bladder neck. The tumor invades focally the intraprostatic portion of the right seminal vesicle. The margins of resection are free of tumor.

Please refer to the previous report for the diagnosis of the pelvic lymph nodes.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES - A prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (3.5 x 2.0 x 4.8 cm, 42 gm, postfixation) has the usual shape. The soft tissue present along the left posterolateral aspects of the prostate appears more abundant than along the right side. A nodule is palpated on the right base region. Blue ink is applied to surfaces of the prostate (anterior apex and under flap on left posterior surface) which do not represent the true margin of resection.

SECTION CODE: C1-C3, right seminal vesicle and segment of right vas deferens from the base towards the tip; C4-C6, left seminal vesicle and segment of left vas deferens from the base towards the tip; C7, C8, prostatic base right border; C9-C11,

[page 4 of 4]
Accession: [REDACTED]

Specimen Date/Time: [REDACTED]

prostatic base right posterior border; C12-C19, prostatic base central portion; C20-C22, prostatic base left border; C23-C25, prostatic base left posterior border; C27-C29, apex anterior; C30, C31, apex left; C32, C33, apex posterior; C34, C35, apex right; C36, C37, detached portions from margin of resection according to specimen radiograph; C38-C49, sections of the three cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked ink green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (23-29, 42, 43 and 46) and orange ink (C38, 41, 44-47 and 49) denote surfaces that do not represent the true margin of resection.

SNOMED CODES

[REDACTED]

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria:	10/23/13	Yes	No

Source: NCI Genomic Data Commons file ef9598b9-0ad6-456f-9dcd-bcc1aa475632 (TCGA-KK-A8IJ.F224443D-410F-4F1E-9CA0-04A652985616.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).